Somatic mutation profile of tumor specimen TCGA-D5-6926-01A (aliquot TCGA-D5-6926-01A-11D-1924-10) from TCGA case TCGA-D5-6926, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 65.1 years (23,768 days).
Specimen TCGA-D5-6926-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7073f00-b8b2-4108-bbf8-c9aead897155.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6926-10A (Blood Derived Normal), aliquot TCGA-D5-6926-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/742c7bed-76ba-478f-bd20-85d394753999

The open-access MAF lists 115 somatic variants for this specimen: 83 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 29, Nonsense Mutation 4, Splice Site 3, RNA 1, 3'UTR 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3871C>T p.Q1291* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as rs1561588104, CM021065, CM053765, COSV57321476, COSV57325789, COSV57375930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 21/35 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.4516G>A p.G1506R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as rs376434066; called by muse, mutect2
- ADSL | c.1022T>G p.L341W | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53406947, COSV53409871; called by muse, mutect2, varscan2
- AKAP9 | c.4586T>G p.L1529* | Nonsense Mutation (SNP) | VAF 26/195 reads (13%) | catalogued as COSV62340147; called by muse, mutect2, varscan2
- AMOTL1 | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100133629; called by muse, mutect2, varscan2
- APC | c.5635G>T p.A1879S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs587779799, COSV57341866; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ARFGEF1 | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 72/420 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); catalogued as COSV99141081; called by muse, varscan2
- ASF1A | c.418T>A p.L140M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57647361; called by muse, mutect2, varscan2
- ATAD2B | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750064696, COSV99476804; called by muse, mutect2, varscan2
- BRF2 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV99604696; called by muse, mutect2
- C2orf78 | c.1055C>A p.P352Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV101280896; called by muse, mutect2, varscan2
- CCDC110 | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV56869678; called by muse, mutect2, varscan2
- CCDC151 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.933); catalogued as COSV62697327; called by muse, mutect2, varscan2
- CCDC174 | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100358409; called by muse, mutect2, varscan2
- CDH11 | c.1642+1G>A p.X548_splice | Splice Site (SNP) | VAF 36/99 reads (36%) | catalogued as COSV51753094; called by muse, varscan2
- CNGB3 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100183382, COSV60685347; called by muse, mutect2, varscan2
- COL25A1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as rs760689752, COSV67647027; called by muse, mutect2, varscan2
- COL5A1 | c.4537G>A p.G1513S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489565447, COSV100879461; called by muse, mutect2
- CP | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs199930098; called by muse, mutect2, varscan2
- CPA2 | c.1144A>G p.R382G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1383874117, COSV99743756; called by muse, varscan2
- CSMD3 | c.7223C>T p.T2408M (on ENST00000297405 / NM_001363185.1; = p.T2304M on NM_052900.3) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs370458785; called by muse, mutect2, varscan2
- CSMD3 | c.6147G>C p.L2049F (on ENST00000297405 / NM_001363185.1; = p.L1945F on NM_052900.3) | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99824027; called by muse, mutect2
- CYTH3 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.722); catalogued as rs184752712; called by muse, mutect2, varscan2
- DDR2 | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs771898787, COSV63369618; called by muse, mutect2, varscan2
- DGKB | c.1457T>G p.V486G | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV99336254; called by muse, mutect2, varscan2
- DNAH10 | c.3292C>T p.R1098C (on ENST00000409039; = p.R1037C on NM_207437.3) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs138397621; called by muse, mutect2, varscan2
- DQX1 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV66352992; called by muse, mutect2, varscan2
- EDNRB | c.629C>A p.S210Y (on ENST00000377211 / NM_001201397.1; = p.S120Y on NM_000115.5) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57519460; called by muse, mutect2, varscan2
- EPS15L1 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1297220753, COSV50167451; called by muse, mutect2, varscan2
- ESR2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV50828466; called by muse, mutect2, varscan2
- FAM227B | c.1405T>G p.F469V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100174430; called by muse, mutect2, varscan2
- FCRL3 | c.383C>G p.T128S | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV100942799; called by muse, mutect2, varscan2
- GLI3 | c.2474C>T p.T825M | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs952113977, COSV67885787; called by muse, mutect2, varscan2
- GPR101 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs751971846, COSV53237468; called by muse, mutect2, varscan2
- GRIK2 | c.1654G>A p.V552I | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs780955412, COSV59712607; called by muse, mutect2, varscan2
- KCNQ3 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV101196183, COSV66464751; called by muse, mutect2, varscan2
- KIF21A | c.1223G>C p.R408T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62768081; called by muse, mutect2, varscan2
- LAMB4 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV52714575; called by muse, mutect2, varscan2
- LAMC2 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV51452887; called by muse, mutect2, varscan2
- LILRB2 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs775537731, COSV58743576; called by muse, mutect2, varscan2
- LMOD1 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs372721398; called by muse, mutect2, varscan2
- MACF1 | c.15873G>T p.L5291F (on ENST00000372915; = p.L3224F on NM_012090.5) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV99241064; called by muse, mutect2, varscan2
- MYH15 | c.5428G>A p.A1810T | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99842190; called by muse, mutect2
- NAV3 | c.4493G>A p.R1498H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1340834228, COSV57065116; called by muse, mutect2, varscan2
- NAV3 | c.4586G>A p.R1529H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368227685; called by muse, mutect2, varscan2
- NDOR1 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1472481692, COSV61286740; called by muse, mutect2, varscan2
- NLRP14 | c.1373C>G p.S458C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV55064690; called by muse, mutect2, varscan2
- NRXN3 | c.1855C>T p.R619C (on ENST00000335750 / NM_001330195.2; = p.R246C on NM_004796.6) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764624479, COSV59714381; called by muse, mutect2, varscan2
- OR9G1 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56448909; called by muse, mutect2
- PCDHGB5 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs1391939612, COSV53908798; called by muse, mutect2, varscan2
- PDE11A | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1456049901, COSV53687892; called by muse, mutect2, varscan2
- PDE1B | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs200096201; called by muse, mutect2, varscan2
- POLRMT | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.473); catalogued as rs1425882374, COSV52112858; called by muse, mutect2, varscan2
- PPEF1 | c.222T>A p.H74Q | Missense Mutation (SNP) | VAF 62/322 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV62995225; called by muse, mutect2, varscan2
- PRAMEF2 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as COSV53572968; called by muse, mutect2, varscan2
- PRKCG | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.069); catalogued as COSV99668499; called by muse, mutect2, varscan2
- RBMS3 | c.194T>G p.I65S | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56134014; called by muse, mutect2, varscan2
- RP1 | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55111509; called by muse, mutect2, varscan2
- RYR3 | c.4910C>T p.T1637I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV101211952; called by muse, mutect2, varscan2
- SBNO1 | c.3452C>G p.S1151C (on ENST00000420886; = p.S1150C on NM_018183.5) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV99928684, COSV99929564; called by muse, mutect2, varscan2
- SCD | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64852875; called by muse, mutect2, varscan2
- SCYL2 | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as COSV62567820; called by muse, mutect2, varscan2
- SLC24A4 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); catalogued as rs1297436330, COSV54108356; called by muse, mutect2, varscan2
- SLFN13 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs138677586; called by muse, mutect2, varscan2
- SNX13 | c.329T>A p.F110Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as COSV68064050; called by muse, mutect2, varscan2
- SORCS3 | c.2106G>C p.Q702H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV63793599, COSV63793659, COSV63797555; called by muse, mutect2, varscan2
- SOX7 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs142748053; called by muse, mutect2, varscan2
- TECRL | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376739815; called by muse, mutect2, varscan2
- TFPI2 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55990116; called by muse, mutect2, varscan2
- TJP2 | c.342+2dup p.X114_splice | Splice Site (INS) | VAF 73/152 reads (48%) | catalogued as rs1459251470; called by mutect2, pindel, varscan2
- TMEM119 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs374614992; called by muse, mutect2, varscan2
- TMOD2 | c.39del p.N14Tfs*16 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV51042908, COSV99988018; called by mutect2, pindel, varscan2
- TTN | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | PolyPhen probably damaging (0.932); catalogued as COSV59914433, COSV60336217; called by muse, mutect2, varscan2
- UNC13B | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541221911, COSV65931696; called by muse, mutect2, varscan2
- ZC3H7A | c.994G>C p.G332R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV63268741; called by muse, mutect2, varscan2
- ZNF189 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as rs745560222, COSV52274666; called by muse, mutect2, varscan2
- ZNF385B | c.1118A>C p.N373T | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100415743; called by muse, mutect2, varscan2
- ZNF700 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as COSV54311138; called by muse, mutect2
- ZNF804A | c.744A>T p.R248S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56434956; called by muse, mutect2, varscan2
- ALG6 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.028); called by muse, mutect2
- CCZ1 | c.513_522+16del p.X171_splice | Splice Site (DEL) | VAF 76/264 reads (29%) | called by mutect2, varscan2
- ANO7 | c.1431G>A p.P477= (on ENST00000274979; = p.P423= on NM_001370694.2) | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs757756741, COSV51469010; called by muse, mutect2, varscan2
- ATP8A2 | c.2625G>A p.V875= | Silent (SNP) | VAF 123/221 reads (56%) | catalogued as rs752925331, COSV54939799; called by muse, mutect2, varscan2
- C8orf76 | c.558G>A p.A186= | Silent (SNP) | VAF 76/125 reads (61%) | catalogued as rs939211239, COSV52690022; called by muse, mutect2, varscan2
- CNGB3 | c.408G>T p.V136= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as rs1446909448, COSV60685692, COSV60690252; called by muse, mutect2, varscan2
- COL12A1 | c.7260C>A p.G2420= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV59390857; called by muse, mutect2, varscan2
- ELF4 | c.708A>G p.K236= | Silent (SNP) | VAF 46/56 reads (82%) | catalogued as COSV57451623; called by muse, mutect2, varscan2
- FGD3 | c.1242C>T p.S414= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1564164931, COSV61595828; called by muse, mutect2, varscan2
- GZMA | c.654C>T p.C218= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs374569624; called by muse, mutect2, varscan2
- HRNR | c.657C>T p.D219= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV64255070; called by muse, mutect2, varscan2
- IGHV4-31 | c.117C>T p.L39= | Silent (SNP) | VAF 58/229 reads (25%) | catalogued as rs1165948489; called by muse, varscan2
- IRX2 | c.267G>A p.A89= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV57409959; called by muse, mutect2, varscan2
- KLHL1 | c.27C>T p.F9= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV64767874; called by muse, mutect2, varscan2
- KLHL31 | c.1047G>A p.T349= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs745343752, COSV63881520; called by muse, mutect2, varscan2
- KRTAP21-1 | c.42C>T p.S14= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs528918166, COSV58646151; called by muse, mutect2, varscan2
- LGI4 | c.1545C>T p.F515= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV59532782; called by muse, mutect2, varscan2
- LRP2 | c.6402G>T p.L2134= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV55543511; called by muse, mutect2, varscan2
- MUC16 | c.37668G>A p.K12556= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as rs1365026047, COSV101197839, COSV67449633; called by muse, mutect2, varscan2
- MXRA5 | c.6390C>T p.S2130= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs761305099, COSV54226258; called by muse, mutect2, varscan2
- PCDHB7 | c.2307C>T p.I769= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV50755796, COSV50770576; called by muse, mutect2, varscan2
- PCDHGB3 | c.1794G>T p.S598= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53908773, COSV53989508; called by muse, mutect2, varscan2
- PNPLA1 | c.465G>A p.P155= (on ENST00000394571 / NM_001374623.1; = p.P60= on NM_173676.2) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs369840888, COSV100462619; called by muse, varscan2
- POU4F3 | c.450C>T p.G150= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV57945696; called by muse, mutect2
- R3HDM2 | c.1599T>C p.Y533= | Silent (SNP) | VAF 74/139 reads (53%) | catalogued as COSV100714932; called by muse, mutect2, varscan2
- SCUBE3 | c.1332G>A p.T444= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs756320758, COSV51455268; called by muse, mutect2, varscan2
- SLC7A5 | c.1053C>T p.F351= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs199932832, COSV55363174; called by muse, mutect2, varscan2
- SNRPA1 | c.330A>G p.A110= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99574413; called by muse, mutect2, varscan2
- SULF1 | c.1693T>C p.L565= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1387122747; called by muse, mutect2
- SYCP2L | c.1479G>A p.P493= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs376863466, COSV51653028; called by muse, mutect2, varscan2
- THBS3 | c.2556T>C p.T852= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100103833; called by muse, mutect2, varscan2
- CCNQP1 | n.191A>G | RNA (SNP) | VAF 21/119 reads (18%) | catalogued as rs770856524; called by muse, mutect2, varscan2
- SACS | c.*682A>T | 3'UTR (SNP) | VAF 20/224 reads (9%) | catalogued as COSV99522608; called by muse, mutect2
- ZNF627 | c.-2A>T | 5'UTR (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100741425; called by muse, mutect2, varscan2
